Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040027-09A.3 (aliquot TARGET-15-SJMPAL040027-09A.3-01D) from TARGET case TARGET-15-SJMPAL040027, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.5 years (5,657 days).
Specimen TARGET-15-SJMPAL040027-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c2fb7eb-cbe1-4af1-9a26-8a937f72c5a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040027-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040027-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1184f6dc-196e-4eba-a84e-b108c98bed14

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 3, In Frame Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 72/78 reads (92%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, varscan2
- CEP192 | c.1934C>A p.S645* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV58068123; called by muse, varscan2
- CPT1B | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs368302579; called by muse, mutect2, varscan2
- FLT3 | c.1767_1787dup p.R595_E596insDFYVDFR | In Frame Ins (INS) | VAF 20/69 reads (29%) | catalogued as COSV54053514, COSV54059730, COSV54060158, COSV54078758; called by mutect2, varscan2
- GLYAT | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1565053353; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4596G>T p.E1532D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.321); called by muse, mutect2
- DHX57 | c.2078G>A p.G693D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXT1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- FAM200A | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- FSCN1 | c.1106C>A p.T369K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.048); called by muse, mutect2
- SALL3 | c.3852C>A p.S1284R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- USP9X | c.2878-2A>C p.X960_splice | Splice Site (SNP) | VAF 22/22 reads (100%) | called by muse, mutect2, varscan2
- VAV3 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- VPS51 | c.1682T>G p.V561G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF57 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAMTS18 | c.1473G>A p.A491= | Silent (SNP) | VAF 107/227 reads (47%) | catalogued as rs148669189, COSV51400093; called by muse, mutect2, varscan2
- EFCAB6 | c.4068C>T p.N1356= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- PCDHA11 | c.123C>T p.H41= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs1428940405, COSV56551586; called by muse, mutect2, varscan2
- SLC35D3 | c.255C>A p.S85= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2, varscan2
- TUBA3C | c.717G>A p.T239= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as rs397839852; called by muse, mutect2, varscan2
